Gene-level copy-number profile of tumor specimen TCGA-A4-A5Y1-01A from TCGA case TCGA-A4-A5Y1, project TCGA-KIRP (Kidney Renal Papillary Cell Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage III; Age at diagnosis: 75.4 years (27,541 days).
Specimen TCGA-A4-A5Y1-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-KIRP.a236f7df-f7eb-4c48-940f-2828c9c51023.ascat3.gene_level_copy_number.v36.tsv, workflow ASCAT3 (allele-specific copy number) on an Affymetrix SNP 6.0 array pair, germline comparator TCGA-A4-A5Y1-11A (solid tissue normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 814 have no estimate. GDC also holds other gene-level copy-number files for this specimen, not rendered: ASCAT2; ABSOLUTE LiftOver.
https://portal.gdc.cancer.gov/files/9c18956f-7bf8-4156-8009-f55ae89574ce

Most common (modal) total copy number across autosomal genes: 4 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 2: 3,537; copy number 3: 29; copy number 4: 23,692; copy number 5: 2,383; copy number 6: 21,123; copy number 7: 1,487; copy number 8: 4,855; copy number 9: 1,094; copy number 10: 1,007; copy number 11: 484; copy number 13: 22; copy number 14: 94; copy number 20: 2.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, aliquot TCGA-A4-A5Y1-01A-11D-A28F-01): tumor purity 0.77, ploidy 2.61, whole-genome doublings 1.

Homozygous deletions (total copy number 0; autosomes only): none.

Amplified relative to the modal value (total copy number ≥ 9, i.e. more than twice the modal value of 4; autosomes only): 2,676 genes in 7 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:237,042,184–248,919,946, 274 genes, copy number 9 (within-gene range 8–9) (broad region; genes not listed).
- chr3:73,182,501–81,105,182, 72 genes, copy number 10 (broad region; genes not listed).
- chr12:125,958,688–129,016,663, 70 genes, copy number 9 (broad region; genes not listed).
- chr13:45,263,690–45,851,753, 21 genes, copy number 13: AL138963.2, TPT1, SNORA31B, SNORA31, AL138963.3, TPT1-AS1, AL138963.1, RCN1P2, SLC25A30, SLC25A30-AS1, PPIAP25, COG3, ERICH6B, RNA5SP27, TIMM9P3, COX4I1P2, LINC01055, AKR1B1P4, CBY2, Metazoa_SRP, SIAH3.
- chr13:47,307,082–114,337,626, 818 genes, copy number 9–14 (broad region; genes not listed).
- chr14:105,836,765–105,856,218, 2 genes, copy number 20: IGHD, IGHM.
- chr16:11,555–35,912,516, 1,419 genes, copy number 10–11 (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 0. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
